Somatic mutation profile of tumor specimen MBCProject_1540_T1_WES (aliquot MBCProject_1540_T1_WES_1) from CMI case MBCProject_1540, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 51.5 years (18,808 days).
Specimen MBCProject_1540_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 418dcae8-e86a-4a2b-be60-267c4ae6f3b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1540_SALIVA (Saliva), aliquot MBCProject_1540_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a039bda7-c7ae-4ee9-bf93-ab36cdde1e05

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 5, Silent 4, RNA 3, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATR | c.5545G>C p.E1849Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63384492, COSV63387168; called by muse, mutect2, varscan2
- KCNK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57279943; called by muse, mutect2
- SEL1L2 | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53158745; called by muse, mutect2
- SLC1A4 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs765089126; called by mutect2, varscan2
- SPTBN4 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1231607130; called by muse, varscan2
- TAPBPL | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 15/282 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1389826174, COSV99869439; called by muse, mutect2
- TCF4 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM125348, COSV61906615; called by muse, mutect2
- AGTPBP1 | c.2582_2584del p.K861_L862delinsM (on ENST00000357081 / NM_001330701.2; = p.K821_L822delinsM on NM_015239.2) | In Frame Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- ATR | c.5575G>A p.E1859K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- FLNA | c.3796G>C p.E1266Q | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2
- RABL3 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- SPTBN4 | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, varscan2
- ACBD5 | c.120G>A p.V40= (on ENST00000375888 / NM_001352568.1; = p.V42= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 32/129 reads (25%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3870A>G p.Q1290= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- KCNC2 | c.546C>T p.D182= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- KPRP | c.996G>A p.P332= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs764394096, COSV64221781; called by muse, mutect2, varscan2
- AP000679.1 | n.558G>T | RNA (SNP) | VAF 14/223 reads (6%) | called by muse, mutect2
- HYDIN | c.-23-16902T>A | Intron (SNP) | VAF 22/108 reads (20%) | catalogued as rs1307561024; called by muse, varscan2
- METTL5 | c.591+106A>G | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as rs1292649547, COSV53627506; called by mutect2, varscan2
- PCMT1 | c.230-5448A>C | Intron (SNP) | VAF 8/71 reads (11%) | catalogued as rs1470266391; called by muse, mutect2
- RBBP4 | c.1212+619T>C | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs1376568252; called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 22/212 reads (10%) | catalogued as rs910081914; called by muse, mutect2
- SNX29P2 | n.1156A>G | RNA (SNP) | VAF 12/100 reads (12%) | catalogued as rs1430353079; called by muse, varscan2
- TUBBP5 | n.1427C>G | RNA (SNP) | VAF 20/48 reads (42%) | catalogued as rs189844666; called by muse, mutect2
